HCMI case HCM-BROD-0234-C49 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9f4d0076-c4a2-46d4-879f-896946338c09

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1938; Vital status: Dead; Days to death: 807 days (2.2 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Spindle cell sarcoma (the primary disease): ICD-O-3 morphology code: 8801/3; ICD-10 code: C49.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 76.5 years (27,950 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G4; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: No; Sites of involvement: Skin.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -13 days.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 619 days (1.7 years); Days to treatment end: 625 days (1.7 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 782 days (2.1 years); Days to treatment end: 793 days (2.2 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Spindle cell sarcoma: ICD-O-3 morphology code: 8801/6; ICD-10 code: C79.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: metastasis; Age at diagnosis: 78.1 years (28,529 days); Days to diagnosis: 579 days (1.6 years).

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Skin, NOS; Days to progression: 0 days.
- Days to follow up: 807 days (2.2 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 794.

Molecular and laboratory tests
- ALK mutation, nos: Negative.
- BRAF mutation, nos (Targeted Sequencing): Negative.
- CDKN2A mutation, nos: Positive; Amino-acid change: c.172C>T.
- EGFR: Negative.
- GNAS mutation, nos: Negative.
- KRAS mutation, nos: Negative.
- PTEN mutation, nos: Negative.
- TP53 mutation, nos (Targeted Sequencing): Negative.
- Test: Negative; Amino-acid change: K27; Histone family: H3.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 63 kg; Height: 167 cm; BMI: 22.6.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol drinks per day: 0; Alcohol days per week: 0.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0234-C49-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0234-C49-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0234-C49-06A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0234-C49-10B: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0234-C49-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 10.
